Somatic mutation profile of tumor specimen C3L-01037-01 (aliquot CPT0170240007) from CPTAC case C3L-01037, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G4; Age at diagnosis: 42.8 years (15,630 days).
Specimen C3L-01037-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee9639b3-d420-4508-b167-65832185dbf9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01037-31 (Blood Derived Normal), aliquot CPT0167230002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cb1abe92-495e-4529-962c-f6fa980468a0

The open-access MAF lists 61 somatic variants for this specimen: 45 protein-altering or splice-affecting, 12 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 12, Nonsense Mutation 4, RNA 2, Intron 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.4328G>A p.R1443H | Missense Mutation (SNP) | VAF 68/816 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs61750142, CM003383; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- CDKN2A | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 114/850 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs11552822, CM085316, CM990358, COSV58683210, COSV58683289, COSV58686242, COSV58694349; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 76/450 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 46/388 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANKFN1 | c.223C>A p.Q75K | Missense Mutation (SNP) | VAF 40/368 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.066); catalogued as rs1344097232; called by muse, mutect2, varscan2
- ANKRD24 | c.2888C>T p.A963V | Missense Mutation (SNP) | VAF 51/482 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.138); catalogued as rs754899693; called by muse, mutect2, varscan2
- CACNA1H | c.6209G>A p.R2070H | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs777897759, COSV52353458; called by muse, mutect2, varscan2
- FBXW11 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 18/296 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.013); catalogued as rs1177616249, COSV51613076; called by muse, mutect2
- GABRA6 | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 74/856 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751098162, COSV50883531; called by muse, mutect2
- GRK7 | c.875G>A p.R292Q | Missense Mutation (SNP) | VAF 51/505 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146685701; called by muse, mutect2, varscan2
- H2BC7 | c.257A>G p.K86R | Missense Mutation (SNP) | VAF 76/756 reads (10%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.926); catalogued as rs151100683; called by muse, mutect2, varscan2
- HS3ST4 | c.38C>T p.P13L | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs922018317; called by muse, mutect2
- KLHL38 | c.1577C>T p.T526M | Missense Mutation (SNP) | VAF 216/1175 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs373548260; called by muse, mutect2, varscan2
- LRP2 | c.2063G>A p.R688H | Missense Mutation (SNP) | VAF 34/692 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs148943767, COSV55571441; ClinVar: uncertain significance; called by muse, mutect2
- MAGEB6 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 53/372 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs769254324, COSV100983828; called by muse, mutect2, varscan2
- NEUROD1 | c.284G>A p.R95H | Missense Mutation (SNP) | VAF 74/844 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV54548947, COSV99717089; called by muse, mutect2
- PABPC1L | c.845A>G p.Q282R | Missense Mutation (SNP) | VAF 56/404 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.835); catalogued as rs765113113; called by muse, mutect2, varscan2
- PPFIA2 | c.2255G>A p.R752Q | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.947); catalogued as rs1369773589, COSV61036725; called by muse, mutect2
- RABL6 | c.368C>T p.A123V | Missense Mutation (SNP) | VAF 33/298 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.033); catalogued as rs774650717; called by muse, mutect2, varscan2
- SYNE1 | c.16112G>A p.R5371Q (on ENST00000367255 / NM_182961.4; = p.R5300Q on NM_033071.3) | Missense Mutation (SNP) | VAF 18/270 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.048); catalogued as rs527462104, COSV55034205, COSV55051690; called by muse, mutect2
- TMEM132C | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 52/450 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs545431831; called by muse, mutect2, varscan2
- ZNF280A | c.175G>A p.V59I | Missense Mutation (SNP) | VAF 23/292 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768517565, COSV57479567; called by muse, mutect2
- ZNF425 | c.703C>T p.R235W | Missense Mutation (SNP) | VAF 43/487 reads (9%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV100955618; called by muse, mutect2
- ACIN1 | c.953A>G p.E318G | Missense Mutation (SNP) | VAF 74/560 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); called by muse, varscan2
- ADAM17 | c.383T>A p.L128Q | Missense Mutation (SNP) | VAF 36/331 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- AGBL2 | c.650T>C p.I217T | Missense Mutation (SNP) | VAF 30/376 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.019); called by muse, mutect2
- ARFGEF1 | c.5407T>C p.Y1803H | Missense Mutation (SNP) | VAF 18/373 reads (5%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.979); called by muse, mutect2
- CNTLN | c.380G>T p.W127L | Missense Mutation (SNP) | VAF 29/239 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CYP2U1 | c.414G>T p.E138D | Missense Mutation (SNP) | VAF 20/508 reads (4%) | SIFT tolerated (0.31); PolyPhen benign (0.107); called by muse, mutect2
- DMP1 | c.13A>T p.I5F | Missense Mutation (SNP) | VAF 48/652 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.062); called by muse, mutect2
- DRC7 | c.2606T>A p.L869H | Missense Mutation (SNP) | VAF 24/336 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.41); called by muse, mutect2
- DSCAML1 | c.5085A>G p.I1695M (on ENST00000321322; = p.I1635M on NM_020693.4) | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.921); called by muse, mutect2
- HYDIN | c.5596C>T p.Q1866* | Nonsense Mutation (SNP) | VAF 15/176 reads (9%) | called by muse, mutect2, varscan2
- MME | c.1445A>G p.Y482C | Missense Mutation (SNP) | VAF 31/358 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NDNF | c.1603C>A p.L535I | Missense Mutation (SNP) | VAF 29/422 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NEB | c.6607A>G p.K2203E | Missense Mutation (SNP) | VAF 36/478 reads (8%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.992); called by muse, mutect2
- NISCH | c.2642G>A p.W881* | Nonsense Mutation (SNP) | VAF 59/668 reads (9%) | called by muse, mutect2
- PCYT1B | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRIMPOL | c.1253G>A p.W418* | Nonsense Mutation (SNP) | VAF 18/222 reads (8%) | called by muse, mutect2
- RTRAF | c.658A>G p.N220D | Missense Mutation (SNP) | VAF 26/341 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); called by muse, mutect2
- SLC12A3 | c.2816G>A p.W939* (on ENST00000563236 / NM_001126108.2; = p.W948* on NM_000339.3) | Nonsense Mutation (SNP) | VAF 18/440 reads (4%) | called by muse, mutect2
- SLC9C2 | c.793_794dup p.Y266Sfs*7 | Frame Shift Ins (INS) | VAF 4/34 reads (12%) | called by mutect2, pindel
- SYNDIG1L | c.142C>A p.P48T | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2
- VPS13D | c.12365A>C p.K4122T | Missense Mutation (SNP) | VAF 28/212 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- WDFY4 | c.739A>G p.I247V | Missense Mutation (SNP) | VAF 7/180 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.001); called by muse, mutect2
- ATRX | c.429G>T p.G143= | Silent (SNP) | VAF 37/235 reads (16%) | called by muse, mutect2, varscan2
- BIRC6 | c.5491T>C p.L1831= | Silent (SNP) | VAF 38/500 reads (8%) | catalogued as rs1216747709; called by muse, mutect2
- CFAP54 | c.7314G>A p.T2438= | Silent (SNP) | VAF 49/504 reads (10%) | catalogued as rs76379187; called by muse, mutect2, varscan2
- COL15A1 | c.609C>T p.F203= | Silent (SNP) | VAF 34/280 reads (12%) | catalogued as COSV66644569; called by muse, mutect2
- CPEB2 | c.480C>T p.T160= | Silent (SNP) | VAF 12/216 reads (6%) | catalogued as rs1286479160; called by muse, mutect2
- ECT2L | c.2163C>T p.Y721= | Silent (SNP) | VAF 24/260 reads (9%) | catalogued as rs192685430; called by muse, mutect2
- FAIM2 | c.888T>A p.I296= | Silent (SNP) | VAF 29/307 reads (9%) | called by muse, mutect2
- HSPA12B | c.906C>T p.G302= | Silent (SNP) | VAF 36/586 reads (6%) | catalogued as rs149068732; called by muse, mutect2
- MBOAT7 | c.1161G>A p.L387= | Silent (SNP) | VAF 32/311 reads (10%) | catalogued as rs150838100; called by muse, mutect2, varscan2
- PCDHAC1 | c.381C>T p.G127= | Silent (SNP) | VAF 36/354 reads (10%) | called by muse, mutect2, varscan2
- PCDHB5 | c.1110T>C p.S370= | Silent (SNP) | VAF 27/314 reads (9%) | called by muse, mutect2
- TACC3 | c.528C>T p.G176= | Silent (SNP) | VAF 52/620 reads (8%) | called by muse, mutect2
- AC010266.2 | n.2016A>G | RNA (SNP) | VAF 7/156 reads (4%) | called by muse, mutect2
- ANK2 | c.2377-147C>T | Intron (SNP) | VAF 23/216 reads (11%) | catalogued as rs538347512; called by muse, mutect2, varscan2
- CCNQP1 | n.394G>A | RNA (SNP) | VAF 49/446 reads (11%) | catalogued as rs772662908; called by muse, mutect2, varscan2
- MYL3 | c.*13+24C>G | Intron (SNP) | VAF 29/458 reads (6%) | called by muse, mutect2
